Somatic mutation profile of tumor specimen ALCH-B3CC-TTP1-A (aliquot ALCH-B3CC-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3CC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.9 years (24,805 days).
Specimen ALCH-B3CC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7d92406-9e99-4150-aac4-e0fd5c5c4b52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3CC-NB1-A (Blood Derived Normal), aliquot ALCH-B3CC-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23d2a45d-3c07-470c-9037-4e226715cf8a

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Intron 3, 5'UTR 2, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 1, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.3586G>T p.V1196F | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV53994071, COSV99665645; called by muse, mutect2
- CACNA1B | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs375412976, COSV53153533; called by muse, mutect2
- CATSPER2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 47/623 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs759192725, COSV100390765; called by muse, mutect2
- CD300LG | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as rs767557360, COSV53222930; called by muse, mutect2
- DSE | c.1612C>T p.R538* | Nonsense Mutation (SNP) | VAF 9/165 reads (5%) | catalogued as rs1280479759, COSV59063236; called by muse, mutect2
- EDN3 | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV61110023; called by muse, mutect2
- EGFR | c.2239_2251delinsC p.L747_T751delinsP | In Frame Del (DEL) | VAF 72/450 reads (16%) | catalogued as rs397509368, COSV51765856; ClinVar: drug response; called by pindel, varscan2*
- ERAP1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs150674566; called by muse, mutect2
- MT1H | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 34/438 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202013248, COSV60091433; called by muse, mutect2
- OR51G1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100429414, COSV100429467; called by muse, mutect2
- PCDHA11 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56546811; called by muse, mutect2
- PCDHA7 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1195624528; called by muse, mutect2
- RPAP3 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs972933355, COSV50043235; called by muse, mutect2
- RSPO1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749070990, COSV62974774; called by muse, mutect2
- SARS2 | c.963-5G>T | Splice Region (SNP) | VAF 54/608 reads (9%) | catalogued as rs1568423770; called by muse, mutect2
- SLC48A1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs868001105, COSV50323394; called by muse, mutect2, varscan2
- TGFBR1 | c.1387-1G>A p.X463_splice | Splice Site (SNP) | VAF 15/399 reads (4%) | catalogued as COSV66626024; called by muse, mutect2
- TTC39A | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.19); catalogued as rs758988769; called by muse, mutect2, varscan2
- ACRBP | c.932A>C p.Q311P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP13 | c.3487G>T p.E1163* | Nonsense Mutation (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 25/252 reads (10%) | called by mutect2, pindel, varscan2
- BOLL | c.687T>G p.C229W | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- CCDC170 | c.1583G>T p.R528M | Missense Mutation (SNP) | VAF 14/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- CEACAM1 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLEC16A | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CR1 | c.2561G>A p.G854E | Missense Mutation (SNP) | VAF 26/580 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DAB1 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- EFCAB8 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.266); called by muse, mutect2
- EFCC1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GTF3C2 | c.1195G>C p.A399P | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- HECTD4 | c.6202C>G p.P2068A | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCTD5 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYLK3 | c.1318G>C p.V440L | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- ONECUT3 | c.1368C>A p.N456K | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.171); called by muse, mutect2
- OR14C36 | c.515T>G p.I172S | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PABPC4 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PHF8 | c.1360G>T p.D454Y (on ENST00000357988 / NM_001184896.1; = p.D418Y on NM_015107.3) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.11); called by muse, mutect2
- POLN | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- POU5F2 | c.271T>C p.W91R | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- PROKR2 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.545); called by muse, mutect2
- SPOP | c.496_516del p.D166_G172del | In Frame Del (DEL) | VAF 38/324 reads (12%) | called by mutect2, pindel
- TENM1 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.391); called by muse, mutect2
- VANGL2 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ZNF740 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2
- ERICH3 | c.4308C>T p.A1436= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as rs912108753, COSV58609106; called by muse, mutect2, varscan2
- FLNA | c.2952C>T p.D984= | Silent (SNP) | VAF 83/398 reads (21%) | catalogued as rs782513930, COSV61046051; called by muse, mutect2, varscan2
- NEFH | c.2409G>A p.L803= | Silent (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2
- OR1J4 | c.48C>T p.D16= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as rs1162080050; called by muse, mutect2
- OR5D18 | c.426C>T p.C142= | Silent (SNP) | VAF 25/270 reads (9%) | catalogued as rs748193440, COSV61737568; called by muse, mutect2
- PADI3 | c.1725C>T p.T575= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as rs767920251, COSV100968471; called by muse, mutect2
- PCDHA4 | c.1854G>A p.A618= | Silent (SNP) | VAF 10/237 reads (4%) | catalogued as rs185992398, COSV63541741; called by muse, mutect2
- RBM48 | c.930A>G p.G310= | Silent (SNP) | VAF 16/313 reads (5%) | called by muse, mutect2
- SBNO2 | c.2589C>T p.R863= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- SI | c.3732C>T p.D1244= | Silent (SNP) | VAF 19/251 reads (8%) | catalogued as rs200449490, COSV100013989, COSV52282786; called by muse, mutect2
- SUPT20HL1 | c.2040T>C p.G680= | Silent (SNP) | VAF 79/307 reads (26%) | called by muse, mutect2, varscan2
- TMEM200B | c.483C>T p.D161= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2
- ZNF536 | c.3138G>T p.R1046= | Silent (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- AFAP1L2 | c.-30G>T | 5'UTR (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- BRCA1 | c.*189G>A | 3'UTR (SNP) | VAF 81/352 reads (23%) | called by muse, mutect2, varscan2
- CYP27B1 | c.387-18C>G | Intron (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- DKK2 | c.-126C>T | 5'UTR (SNP) | VAF 5/89 reads (6%) | catalogued as rs1272929898; called by muse, mutect2
- FOXP3 | c.1146+78G>A | Intron (SNP) | VAF 34/286 reads (12%) | catalogued as rs782695830; called by muse, mutect2, varscan2
- RALGAPA2 | c.1005+66A>G | Intron (SNP) | VAF 6/123 reads (5%) | catalogued as COSV52514656; called by muse, mutect2
